Somatic mutation profile of tumor specimen MMRF_1186_2_BM_CD138pos (aliquot MMRF_1186_2_BM_CD138pos_T1_KHS5U_L14411) from MMRF case MMRF_1186, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.1 years (24,867 days).
Specimen MMRF_1186_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 300c2351-cd38-4578-96bf-7423a083f856.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1186_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1186_2_PB_WBC_C5_KHS5U_L15096; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d809501-324b-42d1-8b73-79cbe174d95d

The open-access MAF lists 87 somatic variants for this specimen: 39 protein-altering or splice-affecting, 5 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 22, Intron 7, 5'UTR 6, Silent 5, RNA 4, 3'Flank 3, Frame Shift Ins 1, 5'Flank 1, Splice Site 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKUB1 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 94/635 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as rs867548527; called by muse, mutect2, varscan2
- BMP1 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.389); catalogued as rs972285384; called by muse, mutect2, varscan2
- CASR | c.1472G>T p.C491F (on ENST00000490131; = p.C568F on NM_000388.4) | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as CM086795; called by muse, mutect2
- ENPP2 | c.2054-1G>A p.X685_splice (on ENST00000075322 / NM_001040092.3; = p.X737_splice on NM_006209.5) | Splice Site (SNP) | VAF 9/85 reads (11%) | catalogued as rs746070485; called by muse, mutect2
- F3 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs755021293; called by muse, mutect2, varscan2
- H1-2 | c.216T>G p.D72E | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs202025821; called by muse, mutect2, varscan2
- IGHD3-9 | c.10T>A p.Y4N | Missense Mutation (SNP) | VAF 20/37 reads (54%) | catalogued as rs782496500; called by muse, mutect2, varscan2
- IGHJ5 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | PolyPhen benign (0); catalogued as rs575391628; called by muse, varscan2
- IGKV4-1 | c.127T>C p.C43R | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776207012; called by muse, varscan2
- IGKV4-1 | c.359C>G p.T120S | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs749276071; called by muse, mutect2, varscan2
- KLF14 | c.932C>A p.S311Y | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.277); catalogued as rs1554470773, COSV60588539; called by muse, mutect2, varscan2
- PDK1 | c.293C>G p.P98R | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757673678; called by muse, mutect2, varscan2
- PLXNC1 | c.1099G>T p.A367S | Missense Mutation (SNP) | VAF 147/777 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.06); catalogued as rs779819475, COSV51574251; called by muse, mutect2, varscan2
- PXDNL | c.3673C>T p.R1225W | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs766445859, COSV62485411; called by muse, mutect2, varscan2
- RMDN2 | c.976dup p.M326Nfs*23 (on ENST00000354545 / NM_001322212.2; = p.M504Nfs*23 on NM_144713.5) | Frame Shift Ins (INS) | VAF 24/80 reads (30%) | catalogued as rs770517879; called by mutect2, varscan2
- ZGRF1 | c.260A>G p.N87S | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs371545389; called by muse, mutect2
- APOBEC3F | c.935C>G p.T312R | Missense Mutation (SNP) | VAF 103/380 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- ARFGEF1 | c.450G>C p.Q150H | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- COL7A1 | c.3360G>T p.R1120S | Missense Mutation (SNP) | VAF 52/369 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DACT3 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ELAC1 | c.391C>G p.P131A | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ENTPD6 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FANCG | c.967A>T p.I323F | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2
- FAT1 | c.11148C>A p.N3716K | Missense Mutation (SNP) | VAF 74/451 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- FAT4 | c.1943A>T p.D648V | Missense Mutation (SNP) | VAF 62/288 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBL | c.86del p.G29Afs*58 | Frame Shift Del (DEL) | VAF 35/103 reads (34%) | called by mutect2, pindel, varscan2
- FREM2 | c.5262T>G p.G1754= | Splice Region (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- MAD1L1 | c.1303A>T p.M435L | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.2425G>T p.A809S | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- PHKA1 | c.2694G>T p.M898I | Missense Mutation (SNP) | VAF 86/146 reads (59%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PI4KB | c.322G>A p.V108M (on ENST00000368873 / NM_001369623.1; = p.V120M on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RANBP2 | c.9441T>A p.N3147K | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SERPINH1 | c.322C>A p.H108N | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- SLIT3 | c.2462G>T p.G821V | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLITRK1 | c.684A>C p.E228D | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TMEM94 | c.1711G>C p.D571H | Missense Mutation (SNP) | VAF 108/389 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TSHZ3 | c.3086T>C p.V1029A | Missense Mutation (SNP) | VAF 88/321 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBASH3B | c.1312G>C p.D438H | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USPL1 | c.3006T>G p.H1002Q | Missense Mutation (SNP) | VAF 89/372 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ALDH1L1 | c.744G>A p.T248= | Silent (SNP) | VAF 70/160 reads (44%) | catalogued as rs575496620, COSV56411317, COSV56415451; called by muse, mutect2, varscan2
- B4GALT5 | c.246C>T p.D82= | Silent (SNP) | VAF 56/258 reads (22%) | catalogued as rs761984732; called by muse, mutect2, varscan2
- CYP26B1 | c.309C>A p.R103= | Silent (SNP) | VAF 48/457 reads (11%) | called by muse, mutect2, varscan2
- FNDC1 | c.5514C>T p.H1838= | Silent (SNP) | VAF 11/326 reads (3%) | catalogued as rs1273957472; called by muse, mutect2
- SATB2 | c.1239A>G p.V413= | Silent (SNP) | VAF 34/160 reads (21%) | catalogued as rs148608261; called by muse, mutect2, varscan2
- BCKDHB | c.*1617G>C | 3'UTR (SNP) | VAF 21/149 reads (14%) | called by muse, mutect2, varscan2
- BDNF | c.-22+699A>T | Intron (SNP) | VAF 218/1035 reads (21%) | called by muse, mutect2, varscan2
- CACNA1C | c.*442C>A | 3'UTR (SNP) | VAF 30/157 reads (19%) | catalogued as rs1161880131; called by muse, mutect2, varscan2
- CBLB | chr3:105869346 G>T | 5'Flank (SNP) | VAF 30/240 reads (13%) | called by muse, mutect2, varscan2
- CBX3 | c.*572A>C | 3'UTR (SNP) | VAF 70/571 reads (12%) | called by muse, varscan2
- CDH8 | c.*1324G>C | 3'UTR (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2
- CNOT2 | c.1392-806G>T | Intron (SNP) | VAF 24/112 reads (21%) | called by muse, mutect2, varscan2
- DBNL | c.*5028C>A | 3'UTR (SNP) | VAF 27/368 reads (7%) | called by muse, mutect2
- DCHS2 | n.6895T>C | RNA (SNP) | VAF 86/417 reads (21%) | called by muse, mutect2, varscan2
- DNAJC15 | c.*1445C>G | 3'UTR (SNP) | VAF 36/158 reads (23%) | called by muse, mutect2, varscan2
- ELL2 | c.*1074T>G | 3'UTR (SNP) | VAF 119/273 reads (44%) | called by muse, mutect2, varscan2
- EPOP | c.-420_-417del | 5'UTR (DEL) | VAF 16/54 reads (30%) | called by pindel, varscan2
- EVI2A | chr17:31316413 G>T | 3'Flank (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- GABRG1 | c.*1416T>G | 3'UTR (SNP) | VAF 53/126 reads (42%) | called by muse, mutect2, varscan2
- GABRQ | c.*2040G>T | 3'UTR (SNP) | VAF 32/269 reads (12%) | called by muse, mutect2, varscan2
- H1-10 | c.-11C>T | 5'UTR (SNP) | VAF 49/101 reads (49%) | called by muse, mutect2, varscan2
- HYPK | c.-3908A>G | 5'UTR (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2
- IKZF1 | c.*2222G>T | 3'UTR (SNP) | VAF 36/197 reads (18%) | called by muse, mutect2, varscan2
- LRRC10 | c.*495G>A | 3'UTR (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- LUM | c.*1365T>G | 3'UTR (SNP) | VAF 18/164 reads (11%) | called by muse, mutect2
- MAGI2 | c.*242A>G | 3'UTR (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- MDGA2 | chr14:46839767 T>G | 3'Flank (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- NAV1 | c.*5654T>C | 3'UTR (SNP) | VAF 61/222 reads (27%) | catalogued as rs1467789094; called by muse, mutect2, varscan2
- NGEF | c.-75+263C>G | Intron (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- PAEP | c.*64C>A | 3'UTR (SNP) | VAF 45/339 reads (13%) | called by muse, mutect2, varscan2
- PLK2 | c.*428A>C | 3'UTR (SNP) | VAF 51/103 reads (50%) | called by muse, mutect2, varscan2
- PRKG1 | c.*2300C>T | 3'UTR (SNP) | VAF 34/156 reads (22%) | catalogued as rs892503026; called by muse, mutect2, varscan2
- RASSF6 | chr4:73571979 A>G | 3'Flank (SNP) | VAF 33/155 reads (21%) | called by muse, mutect2, varscan2
- RGSL1 | c.1494+110C>T | Intron (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- RNF5P1 | n.280C>G | RNA (SNP) | VAF 7/226 reads (3%) | called by muse, mutect2
- SCARA3 | c.*1255G>T | 3'UTR (SNP) | VAF 84/252 reads (33%) | called by muse, mutect2, varscan2
- SLC22A3 | c.*1032C>G | 3'UTR (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- SLC22A6 | c.-16G>T | 5'UTR (SNP) | VAF 21/121 reads (17%) | called by muse, mutect2, varscan2
- SLITRK1 | c.*236T>A | 3'UTR (SNP) | VAF 26/116 reads (22%) | called by muse, mutect2, varscan2
- SNORD116-1 | n.79C>T | RNA (SNP) | VAF 104/486 reads (21%) | called by muse, mutect2, varscan2
- TFAP2D | c.-57T>C | 5'UTR (SNP) | VAF 67/253 reads (26%) | catalogued as rs912134437, COSV50437658, COSV99145737, COSV99145767; called by muse, mutect2, varscan2
- TMEM94 | c.2086+110G>A | Intron (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- TNFRSF11A | c.*1720G>A | 3'UTR (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- TPP1 | c.230-11A>G | Intron (SNP) | VAF 46/304 reads (15%) | called by muse, mutect2, varscan2
- TUBB8P7 | n.894+259C>T | Intron (SNP) | VAF 40/100 reads (40%) | catalogued as rs1278172815; called by muse, mutect2, varscan2
- TXLNGY | n.3363T>G | RNA (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- WRAP53 | c.-1743C>T | 5'UTR (SNP) | VAF 39/145 reads (27%) | called by muse, mutect2, varscan2
- XIAP | c.*1014G>T | 3'UTR (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
